Somatic mutation profile of tumor specimen MP2PRT-PAPWDJ-TMP1-A (aliquot MP2PRT-PAPWDJ-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPWDJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (970 days).
Specimen MP2PRT-PAPWDJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d8d1681-e982-44cf-8f74-b031de538f7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWDJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWDJ-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd84464e-21e9-4d71-9c3d-7e7745ae181c

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 75/343 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 49/331 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSMD3 | c.7969T>A p.F2657I (on ENST00000297405 / NM_001363185.1; = p.F2553I on NM_052900.3) | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV52285708; called by muse, mutect2, varscan2
- DGKB | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs1458240274, COSV99340130; called by muse, varscan2
- GATA6 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 161/525 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs753379725, COSV52525069; called by muse, mutect2, varscan2
- IRX4 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 21/424 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1048121863, COSV51471995; called by muse, mutect2
- KHDC3L | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV100951129, COSV64869870; called by muse, mutect2
- KRT25 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 163/550 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1340533047; called by muse, mutect2, varscan2
- LTBP2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 140/412 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765793427, COSV100000207; called by muse, mutect2, varscan2
- PCDHA7 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.161); catalogued as rs138671187; called by muse, mutect2, varscan2
- PHF21B | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 27/425 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448839516, COSV57557066; called by muse, mutect2
- KL | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NLRP1 | c.14_15dup p.W6Pfs*12 | Frame Shift Ins (INS) | VAF 94/363 reads (26%) | called by mutect2, pindel, varscan2
- PCDHA9 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 38/792 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- SLC2A5 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP33 | c.279C>T p.S93= | Silent (SNP) | VAF 27/368 reads (7%) | catalogued as COSV50119528; called by muse, mutect2
- CYP2C9 | c.622T>C p.L208= | Silent (SNP) | VAF 21/277 reads (8%) | catalogued as CM014893; called by muse, mutect2
- JAKMIP1 | c.1506C>T p.Y502= | Silent (SNP) | VAF 40/732 reads (5%) | catalogued as rs753975251, COSV51523247; called by muse, mutect2
